FM case AD15662 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/d91c5608-1c37-42dc-807e-8783db25d6be

Male, 52.8 years: Carcinoma, undifferentiated, NOS (ICD-O-3 8020/3) of the prostate gland; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
